Somatic mutation profile of tumor specimen TCGA-FY-A3R9-01A (aliquot TCGA-FY-A3R9-01A-11D-A21Z-08) from TCGA case TCGA-FY-A3R9, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 66.3 years (24,215 days).
Specimen TCGA-FY-A3R9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 022e86fd-90ab-46fa-bbe2-a4dd8044ed07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FY-A3R9-10A (Blood Derived Normal), aliquot TCGA-FY-A3R9-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31668726-2a48-4f43-a642-0501f7b939de

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 13, Silent 6, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 89/235 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- AASDH | c.2125G>C p.D709H | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as COSV52709682; called by muse, mutect2
- COL11A1 | c.719G>T p.S240I | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1174962553, COSV62194147; called by muse, mutect2, varscan2
- FMNL1 | c.1438G>A p.V480M | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as COSV58958746; called by muse, mutect2
- HMCN1 | c.14339G>A p.R4780Q | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs111360184, COSV54931107; called by muse, mutect2, varscan2
- KRR1 | c.204G>T p.R68S | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56992422; called by muse, mutect2, varscan2
- OR2M5 | c.766T>A p.L256M | Missense Mutation (SNP) | VAF 90/305 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as rs930675672, COSV63546897; called by muse, mutect2, varscan2
- PRDM4 | c.2387C>A p.S796Y | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.135); catalogued as COSV57307261; called by muse, mutect2
- RAB5C | c.127A>C p.K43Q | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV60526310; called by muse, mutect2, varscan2
- SERPINB3 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as COSV99379684; called by muse, mutect2
- SERPINB4 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.246); catalogued as COSV61984025; called by muse, mutect2, varscan2
- SIDT2 | c.1150G>A p.G384S | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs750809541, COSV54055638; called by muse, mutect2, varscan2
- SIGLEC6 | c.1357A>T p.K453* | Nonsense Mutation (SNP) | VAF 8/138 reads (6%) | catalogued as COSV58436841; called by muse, mutect2
- TRIM39 | c.434A>G p.D145G | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV64956358; called by muse, mutect2, varscan2
- PZP | c.1854_1857del p.T619* | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel, varscan2
- CSMD3 | c.9999A>T p.A3333= (on ENST00000297405 / NM_001363185.1; = p.A3164= on NM_052900.3) | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as COSV52290025; called by muse, mutect2, varscan2
- ODR4 | c.507A>G p.Q169= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as rs777423436, COSV55219113; called by muse, mutect2, varscan2
- PCDHB7 | c.1170C>T p.P390= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs782188852, COSV50806121; called by muse, mutect2
- PCDHGB5 | c.690C>T p.I230= | Silent (SNP) | VAF 37/262 reads (14%) | catalogued as COSV54013748; called by muse, mutect2, varscan2
- POMC | c.471G>T p.V157= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- SEPSECS | c.1227G>T p.G409= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV57207262; called by muse, mutect2, varscan2
